Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A7IN, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A7IN-01A (Primary Tumor).

[page 1 of 2]
ICD-6.3
Pheochromocytoma 8700/0
Adrenal gland NOS C74.9
Q10 1/17/14

Surgical Pathology [OrderID:

Final Results

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS:

1. Adrenal, right, adrenalectomy: Pheochromocytoma.
2. Spleen, splenectomy: Sarcoidosis, no tumor seen, no evidence of metastatic pheochromocytoma seen, see Note.

NOTE: Special stains of GMS and AFB-F are performed. No fungal organisms or mycobacteria are seen. Clinical correlation is recommended to determine the etiology.

Immunoperoxidase and In-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Allocate Order to Protocol: Brief
Clinical History: r/o mets
pheochromocytoma Specimen Taken For Protocol: - Yes

PROCEDURE: Pre-Operative Diagnosis: mets pheochromocytoma
Post-Operative
Diagnosis: same Operative Findings: r adrenal mass, nrl appearing spleen

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, LEFT
2. SPLEEN

GROSS DESCRIPTION:

1. "Right adrenal mass" is an intact adrenal gland with attached fat and a loosely adherent oval maroon nodule (3.5 x 3 x 1.5 cm). Overall, the specimen is 6.4 x 5 x 1.7 cm and weighs 5.5 grams. The adrenal gland itself is 5.7 x 5 x 0.9 cm. The surface of the adrenal gland which has the loosely attached nodule and the nodule are inked black. The nodule is bisected revealing a soft friable hemorrhagic maroon cut surface. Gross photographs are taken. Approximately 50% and 5% of tissue from the center of the nodule are procured for and Approximately 1 x 0.6 x 0.5 cm of normal-appearing periadrenal fat is procured for The procurement was performed by on The remainder of the specimen is placed

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

JobID:

Requested By:

Do not file in Medical Record

[page 2 of 2]
into formalin and submitted to Pathology for permanent. The specimen is received in Pathology and matches the above description. It consists of a brown-tan and orange soft tissue fragment measuring in aggregate 5.5 x 5.0 x 1.2 cm. It appears that the extra soft tissue nodule is outside of and not connected to the bright orange adrenal. The specimen is serially sectioned and entirely submitted in white cassettes labeled 1A-1G with 1A-1E containing adrenal and 1E-1G containing the extraadrenal mass.

2. Received fresh labeled with the patient's name; medical record number, and labeled "spleen" is a splenectomy specimen weighing 111.5 grams and measuring 11 x 5.5 x 2.5 cm. The external surface where a nodule is present is overinked black by . The nodule is then incised revealing a yellow-to-tan nodular area measuring 1.8 x 1.5 x 1.5 cm-in-diameter. Approximately 1 x 1 x 1 cm is procured for I and 1 x 1 x 1 cm of the nodule is procured for by . This is documented by on at hour. Representative sections of nodule are taken and placed in white cassettes labeled . The spleen is serially sectioned and an additional white nodular area is identified at the opposite end of the spleen. This white nodule measures 0.5 cm in greatest diameter. Sections of this nodule are submitted in white cassettes labeled 2C and 2D. No additional nodules are appreciated in the remainder of the spleen. Additional sections of normal-appearing spleen are submitted in white cassettes labeled 2E-2G.

Gross description dictated by
description dictated by

Additional gross

No consultants
Accessioned:
Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

ATTENDING STAFF PATHOLOGIST

Date Report Signed:

H/PA Discrepancy		X

Source: NCI Genomic Data Commons file a36ed1a0-27d6-43fe-a974-ee05c5189f4e (TCGA-QR-A7IN.5D8E8FF7-FC06-428A-9F64-8C22333F44C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).